Somatic mutation profile of tumor specimen 0DSA0C from CCDI case PBCHVU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Oligoastrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.3 years (4,131 days).
Specimen 0DSA0C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f1e9af1-34dd-46db-ad3b-9a735980db89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSA1G (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0d7c288-4075-43bc-8e82-3a41c5c0bc73

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Missense Mutation 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 59/939 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2
- C11orf95 | c.1595del p.P532Rfs*59 | Frame Shift Del (DEL) | VAF 58/538 reads (11%) | called by mutect2, varscan2
- CACNA1F | c.567C>T p.D189= | Silent (SNP) | VAF 54/1098 reads (5%) | catalogued as rs782442179, COSV59907267; called by muse, mutect2
- SIGLEC15 | c.891G>A p.P297= | Silent (SNP) | VAF 83/489 reads (17%) | catalogued as rs778749999, COSV101248972, COSV67181396; called by muse, mutect2, varscan2
- SMAD3 | c.658+9C>A | Intron (SNP) | VAF 32/778 reads (4%) | called by muse, mutect2
